Somatic mutation profile of tumor specimen 0E0JRZ from CCDI case PBCUJI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0E0JRZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bbe3ddef-3ab1-49fc-b788-09cd35302ac4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0E0JS2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca9bba42-5d63-4283-a97d-7c138445eb4f

The open-access MAF lists 3 somatic variants for this specimen: 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIR3DL3 | c.*99del | 3'UTR (DEL) | VAF 10/40 reads (25%) | called by mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 16/148 reads (11%) | called by muse, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 16/352 reads (5%) | called by muse, mutect2
